Somatic mutation profile of tumor specimen MMRF_1388_1_BM_CD138pos (aliquot MMRF_1388_1_BM_CD138pos_T1_KAS5U_L00659) from MMRF case MMRF_1388, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.2 years (29,667 days).
Specimen MMRF_1388_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a5fc267-34df-4200-bfe0-051e8a561662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1388_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1388_1_PB_Whole_C2_KAS5U_L00674; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb3ffe6f-0b64-4baf-b270-4da2c52ccc9e

The open-access MAF lists 147 somatic variants for this specimen: 62 protein-altering or splice-affecting, 15 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 40, Intron 17, Silent 15, Frame Shift Del 6, Nonsense Mutation 5, RNA 4, 5'UTR 4, 3'Flank 3, 5'Flank 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IMPG2 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs786205565; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADPGK | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs1423548101; called by muse, mutect2, varscan2
- AHNAK2 | c.13444A>T p.I4482F | Missense Mutation (SNP) | VAF 61/62 reads (98%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV60911325; called by muse, mutect2
- ATP6V1A | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849976; called by muse, mutect2, varscan2
- DNAH17 | c.9274G>A p.E3092K | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748643058, COSV101103407; called by muse, mutect2, varscan2
- DNAJA2 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV100398808; called by muse, mutect2, varscan2
- FBXO40 | c.644T>C p.F215S | Missense Mutation (SNP) | VAF 91/132 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs556118975; called by muse, mutect2, varscan2
- GPLD1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1331636024, COSV57758727, COSV57759871; called by muse, mutect2, varscan2
- HIVEP2 | c.4801C>T p.H1601Y | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1430532014; called by muse, mutect2, varscan2
- HS6ST2 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 60/69 reads (87%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV63719359; called by muse, mutect2, varscan2
- LAMB4 | c.1759C>G p.P587A | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs772402640, COSV99222209; called by muse, mutect2, varscan2
- MARCKS | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs778823857; called by muse, mutect2, varscan2
- NAP1L4 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs201761556; called by muse, mutect2, varscan2
- NLRP12 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as rs750186083, COSV60747251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSF | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV56574533; called by muse, mutect2, varscan2
- PEG3 | c.2882C>T p.T961I | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV55627966; called by muse, mutect2, varscan2
- SHISA7 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs1440769770; called by muse, mutect2, varscan2
- SLC52A3 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs374661714; called by muse, mutect2, varscan2
- TRA2B | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as COSV52026061; called by muse, mutect2, varscan2
- TRAF3 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 12/14 reads (86%) | catalogued as COSV61023971; called by muse, mutect2, varscan2
- TTN | c.99659G>A p.R33220H (on ENST00000591111; = p.R25796H on NM_003319.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | PolyPhen benign (0.003); catalogued as rs777774818, COSV59915377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP43 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 49/111 reads (44%) | catalogued as rs774698082; called by muse, mutect2
- WEE1 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0.133); catalogued as rs749689471; called by muse, mutect2, varscan2
- ZNF536 | c.3371C>T p.S1124L | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); catalogued as rs745900643, COSV62818623; called by muse, mutect2, varscan2
- ACTG1 | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- ADARB1 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ADARB2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- BUB1B | c.613_614del p.L205Vfs*4 | Frame Shift Del (DEL) | VAF 40/98 reads (41%) | called by pindel, varscan2
- C2orf16 | c.797del p.N266Mfs*5 | Frame Shift Del (DEL) | VAF 47/110 reads (43%) | called by mutect2, varscan2
- CD300A | c.380-1G>C p.X127_splice | Splice Site (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- CHRNB1 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DAP3 | c.93C>G p.S31R | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EIF4A1 | c.1092_1109delinsGTGT p.R365Cfs*5 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | called by pindel, varscan2*
- ENAH | c.1610C>T p.S537F (on ENST00000366844 / NM_001008493.3; = p.S516F on NM_018212.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- EVC | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 30/32 reads (94%) | called by muse, mutect2, varscan2
- GJA9 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- GLIS3 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA4 | c.1276dup p.T426Nfs*14 | Frame Shift Ins (INS) | VAF 28/109 reads (26%) | called by mutect2, pindel, varscan2
- GPRC6A | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHA1 | c.419dup p.S141Ffs*36 | Frame Shift Ins (INS) | VAF 20/30 reads (67%) | called by mutect2, pindel, varscan2
- IGHV3-64 | c.281A>T p.N94I | Missense Mutation (SNP) | VAF 80/82 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- IGLV2-23 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- KNOP1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- LIPE | c.2936T>C p.M979T | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LTBP3 | c.118_141del p.R40_G47del | In Frame Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- MAP4 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 192/277 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MATN2 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- MCMBP | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- MGAT4A | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NFKBIA | c.354_372del p.V119Kfs*39 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel
- PARP10 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNASEL | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF113B | c.243G>T p.R81S | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA4 | c.3254T>C p.L1085P | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCAL1 | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SPATS2L | c.955A>T p.K319* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- SREK1 | c.830_849del p.K277Rfs*7 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- TARDBP | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TAS2R19 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TPPP2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VASN | c.232del p.L78Cfs*30 | Frame Shift Del (DEL) | VAF 61/83 reads (73%) | called by mutect2, pindel, varscan2
- VWA5B1 | c.2461C>T p.Q821* | Nonsense Mutation (SNP) | VAF 34/40 reads (85%) | called by muse, mutect2, varscan2
- AURKA | c.414T>C p.P138= | Silent (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- EGR1 | c.246C>T p.S82= | Silent (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- HSD17B7 | c.6A>G p.R2= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV54418941; called by muse, varscan2
- IGLL5 | c.61A>C p.R21= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as rs772487297, COSV73250883; called by muse, mutect2, varscan2
- IGLV3-25 | c.297A>G p.E99= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs184451737; called by muse, varscan2
- MAP2K3 | c.126G>A p.R42= (on ENST00000342679 / NM_145109.3; = p.R13= on NM_002756.4) | Silent (SNP) | VAF 24/234 reads (10%) | catalogued as rs1454191087, COSV100383861; called by muse, mutect2
- MMP15 | c.453C>T p.Y151= | Silent (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- NYNRIN | c.790C>T p.L264= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs756824618; called by muse, mutect2, varscan2
- PCDH11X | c.717T>C p.V239= | Silent (SNP) | VAF 121/130 reads (93%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1680C>T p.P560= | Silent (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- PDCD11 | c.3879G>A p.L1293= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- RGS16 | c.522G>A p.S174= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs763824190, COSV100842478; called by muse, mutect2, varscan2
- SHANK1 | c.2769A>C p.P923= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- STOX2 | c.741C>T p.S247= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1488403935; called by muse, mutect2, varscan2
- TENT4A | c.2160C>G p.L720= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- AC053481.3 | n.132C>T | RNA (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- AHCTF1 | c.*183C>T | 3'UTR (SNP) | VAF 97/425 reads (23%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25166811 G>A | 3'Flank (SNP) | VAF 25/43 reads (58%) | called by muse, mutect2, varscan2
- C1orf198 | c.*969C>T | 3'UTR (SNP) | VAF 76/115 reads (66%) | called by muse, mutect2, varscan2
- CBX2 | c.288+189G>C | Intron (SNP) | VAF 33/73 reads (45%) | catalogued as COSV53970026, COSV99490969; called by muse, mutect2, varscan2
- CCDC30 | c.1195-404A>G | Intron (SNP) | VAF 10/10 reads (100%) | catalogued as COSV59604047; called by muse, mutect2
- CLRN1 | c.*38T>G | 3'UTR (SNP) | VAF 78/259 reads (30%) | called by muse, mutect2, varscan2
- CLTC | c.*714C>A | 3'UTR (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- CNTN5 | c.*130A>T | 3'UTR (SNP) | VAF 51/108 reads (47%) | catalogued as rs1354140033; called by muse, mutect2, varscan2
- COG2 | c.300+30del | Intron (DEL) | VAF 91/159 reads (57%) | called by mutect2, pindel, varscan2
- CSH2 | c.11-98G>A | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- CYB5R3 | c.*1861C>A | 3'UTR (SNP) | VAF 79/171 reads (46%) | catalogued as rs1341612647; called by muse, mutect2, varscan2
- DEFB134 | c.*38C>G | 3'UTR (SNP) | VAF 67/158 reads (42%) | called by muse, mutect2, varscan2
- DLL4 | c.336+40G>A | Intron (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- EGLN1 | c.*627dup | 3'UTR (INS) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- FABP7 | c.348+1149G>A | Intron (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- FAM32EP | chr12:126457951 G>A | 3'Flank (SNP) | VAF 6/17 reads (35%) | catalogued as rs995264739; called by muse, mutect2
- FKBP15 | c.324+144A>G | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- FRG1BP | n.449G>A | RNA (SNP) | VAF 58/242 reads (24%) | called by muse, mutect2, varscan2
- GID4 | c.*1563G>A | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, varscan2
- GPC6 | c.-590G>A | 5'UTR (SNP) | VAF 51/116 reads (44%) | catalogued as rs1049591947; called by muse, mutect2, varscan2
- GPS2 | c.*76A>G | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- HCCS | c.*602G>A | 3'UTR (SNP) | VAF 34/38 reads (89%) | catalogued as rs886111564; called by muse, mutect2, varscan2
- HDHD5 | c.572-195C>T | Intron (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- HOXB4 | c.*278G>T | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- HOXB4 | c.*277G>A | 3'UTR (SNP) | VAF 11/27 reads (41%) | catalogued as rs935301936; called by muse, mutect2, varscan2
- IFNAR2 | c.841-84G>C | Intron (SNP) | VAF 74/159 reads (47%) | called by muse, mutect2, varscan2
- IRF4 | c.*451C>T | 3'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as rs1561721040; called by muse, mutect2
- ISM1 | c.*244G>A | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- JMY | c.-140G>T | 5'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- KIF6 | c.*4752G>A | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- LETMD1 | c.*690C>A | 3'UTR (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- LGALS8 | c.*133G>A | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- LIMD2 | c.43-62G>A | Intron (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- LINC02206 | n.686G>A | RNA (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- MAFA | c.*895G>A | 3'UTR (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- MAP4 | c.2000-14039C>T | Intron (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- MOB1B | c.*6052A>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs1254930189; called by muse, mutect2
- MORC3 | c.*274dup | 3'UTR (INS) | VAF 44/82 reads (54%) | catalogued as rs1422172618; called by mutect2, varscan2
- MPV17 | chr2:27325642 G>A | 5'Flank (SNP) | VAF 31/67 reads (46%) | catalogued as rs1359532055; called by muse, mutect2, varscan2
- MTMR11 | c.771+52A>G | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40523402 G>A | 5'Flank (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- NCBP1 | c.*1137G>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- NCKAP5 | c.*152G>T | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- NEBL | c.*3497A>C | 3'UTR (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- NELFCD | c.843-105G>A | Intron (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- NREP | c.*775C>G | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- OR12D3 | c.*836A>C | 3'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- OXSR1 | c.292+2526C>T | Intron (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- PDIA3 | c.*1179T>A | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- PLA2R1 | c.3967+744G>A | Intron (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- PPP4R3B | c.*404A>G | 3'UTR (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- PTPRK | chr6:127969482 C>T | 3'Flank (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- PYGO1 | c.*4093C>A | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- RAB2B | c.*16T>C | 3'UTR (SNP) | VAF 95/211 reads (45%) | catalogued as rs1209681939, COSV67235420; called by muse, mutect2, varscan2
- RASSF2 | c.*2082C>T | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- RNF111 | c.1366+89T>A | Intron (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- RNF32 | c.418-74C>T | Intron (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2
- SEMA5A | c.*4196C>T | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.*1034A>G | 3'UTR (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- SMAD4 | c.*2843C>T | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- SNX13 | c.*802C>A | 3'UTR (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2, varscan2
- SNX19 | c.*2181A>T | 3'UTR (SNP) | VAF 60/86 reads (70%) | called by muse, mutect2, varscan2
- TBX19 | c.*568T>A | 3'UTR (SNP) | VAF 51/60 reads (85%) | called by muse, mutect2, varscan2
- TPM2 | c.-55G>A | 5'UTR (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- TRAV23DV6 | c.-6G>A | 5'UTR (SNP) | VAF 32/76 reads (42%) | catalogued as rs761657645; called by muse, mutect2, varscan2
- VAPB | c.*4541G>A | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- YWHAEP5 | n.601G>T | RNA (SNP) | VAF 106/195 reads (54%) | called by muse, mutect2, varscan2
- ZNF486 | c.*298G>A | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- ZNF829 | c.*174T>A | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
